Surgical pathology report (de-identified scan), TCGA case TCGA-GU-A764, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - UT Southwestern Medical Center at Dallas, specimen TCGA-GU-A764-01A (Primary Tumor).

[page 1 of 4]
Results

BIOPSY OR SURGICAL SPECIMEN (Order)

Patient Information

Patient Name

MRN

Sex

DOB

Result Information

Status

Final

Provider Status

Ordered

Entry Date

Component Results

Component

Surgical Pathology

Patient Name:

Lab

Final Diagnosis

- A. Right distal ureter, biopsy:
- Segment of benign ureter
- No carcinoma or dysplasia is seen
- Frozen section diagnosis is confirmed on permanent sections

- B. Left distal ureter, biopsy:
- Segment of benign ureter
- No carcinoma or dysplasia is seen
- Frozen section diagnosis is confirmed on permanent sections

- C. Urinary bladder and prostate, radical cystoprostatectomy:
- Invasive high grade urothelial carcinoma, invasive into muscularis propria and predominantly involving anterior bladder wall
- Tumor measures 4.7 cm in greatest dimension (macroscopic measurement)
- All surgical margins are free of carcinoma and dysplasia
- Nineteen pelvic lymph nodes, negative for metastatic carcinoma (0/19; see parts D, E and F)
- TNM pathologic stage: pT2b N0 Mx
- Bladder with acute and chronic inflammation and reactive urothelial atypia, biopsy site changes, cystitis cystica and focal intestinal metaplasia
- Benign prostatic and seminal vesicle tissue with patchy acute inflammation
- Urethral margin with patchy necrosis, acute inflammation and reactive urothelial atypia
- Frozen section diagnosis of urethral margins is confirmed on permanent sections
- See CAP template below for further details

CAP Template for carcinoma of the urinary bladder:

Specimen: Bladder and prostate

Procedure: Radical cystoprostatectomy

Tumor Site: Anterior bladder wall

Tumor Size: 4.7 cm in greatest dimension

Histologic Type: Urothelial (transitional cell) carcinoma

ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site: Bladder, anterior wall
C67.3
JW 8/13/13

dTPAA Discrepancy		☒
Dual Syn. / Primary Notes		☒

[page 2 of 4]
Associated Epithelial Lesions: None identified

Histologic Grade:

Urothelial Carcinoma (WHO 2004/ISUP): High-grade

Tumor Configuration: Ulcerated

Microscopic Tumor Extension: Tumor invades muscularis propria

Margins: Margins uninvolved by invasive carcinoma

Lymph-Vascular Invasion: Absent

Pathologic Staging (pTNM):

Primary Tumor (pT): pT2b: Tumor invades deep muscularis propria (detrusor muscle)

Regional Lymph Nodes (pN): pN0: No lymph node metastasis
Specify: Number

examined: 19

Specify: Number

involved: 0

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: Urothelial inflammation, biopsy site changes, focal intestinal metaplasia

Ancillary Studies: Not done. Blocks C5 & C6 can be used for additional studies, if needed.

The above pathology diagnosis incorporates data elements as outlined in the CAP Cancer Protocols and Checklists which are based on the AJCC/UICC TNM, 7th edition.

D. Right pelvic lymph nodes, lymphadenectomy:
- Seven lymph nodes, negative for metastatic carcinoma (0/7)

E. Left common iliac and presacral lymph nodes, lymphadenectomy:
- Four lymph nodes, negative for metastatic carcinoma (0/4)

F. Left pelvic lymph nodes, lymphadenectomy:
- Eight lymph nodes, negative for metastatic carcinoma (0/8)

Clinical History

Bladder cancer

Radical cystectomy, orthotopic neobladder diversion, possible ileal conduit.

Source:

A: Right distal ureter margin

B: Left distal ureteral margin

C: Bladder and prostate

D: Right pelvic lymph nodes

E: Common ileacs and presacral

F: Left pelvic lymph nodes

[page 3 of 4]
Gross Description

Specimen A received fresh for frozen section labeled with the patient's name and "right distal ureteral margin". The specimen is a pink-tan ring-shaped tissue fragment measuring 0.4 cm in diameter, 0.2 cm in length. The tissue is entirely submitted for frozen section, subsequently entirely submitted in A1.

Specimen B received fresh for frozen section labeled with the patient's name and "left distal ureteral margin". The specimen is a pink-tan ring-shaped soft tissue fragment measuring 0.6 cm in diameter, 0.3 cm in length. The tissue is entirely submitted for frozen section, subsequently entirely submitted in B1.

Specimen C received in formalin labeled with the patient's name and "bladder prostate".

Type of specimen: Urinary bladder, ureteral stumps, prostate, seminal vesicles
The patient's name, requisition, and specimen containers all match.

Procedure: Radical cystoprostatectomy

Fixative: Received fresh, later placed in formalin

Dimensions: Bladder superior to inferior 8.0 cm, right to left 7.0 cm, anterior to posterior 2.8 cm. Prostate superior to inferior 2.5 cm, right to left 3.2 cm, anterior to posterior 2.7 cm. The right ureteral stump 2.2 cm in length and 0.5 cm in diameter. The left ureteral stump 3.5 cm in length and 0.5 cm in diameter.

Description of findings:

Tumor: The anterior bladder wall reveals a hemorrhagic ulcerated firm tumor mass measuring 4.7 cm superior to inferior, and 2.9 cm left to right. The central portion of the tumor is ulcerated, hemorrhagic and necrotic. On sectioning, dense gray-white solid apparent tumor tissue can be seen invading the full-thickness of the muscularis; however, does not appear grossly to have extended beyond the overlying perivesicular adipose tissue. The posterior bladder wall has a focally hemorrhagic somewhat edematous appearance. The bladder lining in the dome appears grossly unremarkable. The prostate has a normal gray-white lobulated, somewhat spongy appearance. The urethral lining is red-brown, friable, and appears necrotic. The seminal vesicles appear grossly unremarkable. No lymph nodes are identified within the attached perivesicular adipose tissue.

Ink Code: Anterior bladder wall blue, posterior black. Prostate right side orange, left side blue.

Section key:

- C1 urethral margin #1 frozen section
- C2 urethral margin #2 frozen section
- C3 right ureteral resection margin and ureteral orifice
- C4 left ureteral resection margin and left ureteral orifice
- C5-C9 sections of tumor
- C10, C11 sections of posterior bladder wall
- C12 bladder dome
- C13 left lateral wall
- C14 right lateral wall
- C15 trigone
- C16 right prostate apex sectioned radially
- C17, C18 right prostate
- C19 left prostate apex sectioned radially
- C20, C21 left prostate
- C22 right seminal vesicles and vas deferens
- C23 left seminal vesicles and vas deferens

Comment: Fresh tissue was obtained for tissue procurement

Specimen D received in formalin labeled with the patient's name and "right pelvic lymph nodes". The specimen consists of two irregular fragments of focally hemorrhagic lobulated yellow adipose tissue measuring in aggregate 8.5 x

[page 4 of 4]
3.5 x 1.2 cm. Sectioning through the adipose tissue reveals eight apparent lymph nodes ranging in size from 0.7-2.6 cm. The specimen is submitted as follows:

D1 one node bisected
D2 one node bisected
D3 one node bisected
D4 one node bisected
D5 one node bisected
D6 three whole nodes

Specimen E received in formalin labeled with the patient's name and "left common iliac and presacral pelvic lymph nodes". The specimen consists of three fragments of focally hemorrhagic lobulated adipose tissue measuring in aggregate 4.0 x 1.8 x 0.8 cm. Sectioning through the adipose tissue reveals four apparent lymph nodes ranging in size from 0.6-2.9 cm. The specimen is entirely submitted as follows:

E1 one node bisected
E2 three whole nodes

Specimen F received in formalin labeled with the patient's name and "left pelvic lymph nodes". The specimen consists of multiple fragments of focally hemorrhagic lobulated adipose tissue measuring in aggregate 4.8 x .40 x 1.4 cm. Sectioning through the adipose tissue reveals eight apparent lymph nodes ranging in size from 0.4-2.4 cm. The nodes are submitted as follows:

F1 one node bisected
F2 one node bisected
F3 one node bisected
F4 one node bisected
F5 one node bisected
F6 three whole nodes

Microscopic Description
The stain quality is acceptable.

A-F. The microscopic findings are reflected in the diagnoses rendered.

Intraoperative Diagnosis

Time in: Time out:
A1, Right distal ureter margin biopsy: "Negative for carcinoma or high grade dysplasia".

Time in: , Time out:
B1, Left distal ureter: "Negative for carcinoma or high grade dysplasia".

Time in: Time out:
C1, Bladder and prostate urethral margin: "Necrotic tissue with scant viable epithelium with focal atypia, favor reactive, cannot rule out dysplasia".

***Electronically Signed Out By

Results

Pathology Report - Scan on

: Intraoperative Consultation Report

Result History

BIOPSY OR SURGICAL SPECIMEN

- Order Result History Report.

Collection Information

Source: NCI Genomic Data Commons file 1a369756-577c-4d58-adef-524e61d5b3fb (TCGA-GU-A764.55AD4C75-61D8-4377-A4F0-1311CFD6ACA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).